Gene-level copy-number profile of tumor specimen TCGA-85-8355-01A from TCGA case TCGA-85-8355, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.6 years (23,227 days).
Specimen TCGA-85-8355-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.6cf7bc0c-bf35-4144-8f74-75dbe0b295ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8355-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2d7e8f74-4509-48f7-acdc-2e88509de44a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 133; copy number 1: 25,057; copy number 2: 31,862; copy number 3: 1,669; copy number 4: 645; copy number 5: 262; copy number 6: 12; copy number 7: 31; copy number 10: 48; copy number 11: 42; copy number 16: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8355-01A-11D-2292-01): tumor purity 0.23, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 445 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:102,621,061–103,630,912, 7 genes, copy number 5 (within-gene range 3–5): AC063938.1, RNU6-461P, RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11.
- chr3:178,526,505–184,017,939, 110 genes, copy number 6–16 (within-gene range 2–16) (broad region; genes not listed).
- chr18:508,568–5,004,537, 89 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr18:7,231,125–9,254,346, 31 genes, copy number 7 (within-gene range 1–7): LRRC30, AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1.
- chr18:10,380,423–11,914,344, 42 genes, copy number 5 (within-gene range 1–5): AP006219.2, LINC01254, AP006219.3, APCDD1, NAPG, AP001099.1, LINC01887, AP001180.3, CCDC58P1, AP001180.2, AP001180.5, PMM2P1, AP001180.1, PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1, AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2.
- chr19:37,304,451–40,465,764, 166 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,803. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
